CCDI case PBBRZV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/bf66655f-6f0c-461a-b8ff-9e330bdd7793

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 3.3 years (1,211 days).

Biospecimens (3 samples)
- Sample 0DFBL9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFBLF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFBLS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
